Somatic mutation profile of tumor specimen TCGA-GD-A2C5-01A (aliquot TCGA-GD-A2C5-01A-12D-A17V-08) from TCGA case TCGA-GD-A2C5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 53.4 years (19,498 days).
Specimen TCGA-GD-A2C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bf77cbb-16b6-4435-952d-b655345d0420.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GD-A2C5-10A (Blood Derived Normal), aliquot TCGA-GD-A2C5-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93c7647d-0fa9-493a-8f24-610ba32b0876

The open-access MAF lists 294 somatic variants for this specimen: 218 protein-altering or splice-affecting, 71 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 71, Nonsense Mutation 21, Frame Shift Del 4, Intron 2, Splice Site 2, Frame Shift Ins 2, In Frame Ins 1, 5'UTR 1, Nonstop Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FKBP10 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906960, CM111272, COSV58639559; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.3879-1G>A p.X1293_splice | Splice Site (SNP) | VAF 22/45 reads (49%) | hotspot (GDC flag); catalogued as COSV100937745, COSV65046983; called by muse, mutect2, varscan2
- RECQL4 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs771349728, COSV100020571, COSV56742668; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 45/73 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60695469; called by muse, mutect2, varscan2
- ACOT11 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs747945837, COSV56366602; called by muse, mutect2, varscan2
- ACTL9 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as rs782233148, COSV61007382; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.037); catalogued as COSV54450801, COSV54472781; called by muse, mutect2, varscan2
- ADGRE5 | c.2065G>C p.E689Q (on ENST00000242786 / NM_078481.4; = p.E596Q on NM_001784.5) | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as COSV54393600; called by muse, mutect2, varscan2
- ADGRL3 | c.2958C>G p.I986M (on ENST00000506720 / NM_001322402.2; = p.I918M on NM_015236.6) | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101546953, COSV72232107; called by muse, mutect2
- AFMID | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56961441; called by muse, mutect2, varscan2
- AHSG | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56609593; called by muse, mutect2, varscan2
- AJM1 | c.2217C>G p.I739M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV56034445, COSV56034782; called by muse, mutect2
- AL592490.1 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as COSV69428287; called by muse, mutect2, varscan2
- ALG2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV53061043; called by muse, mutect2, varscan2
- ANKRD30A | c.3250G>C p.E1084Q (on ENST00000611781; = p.E1028Q on NM_052997.2) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64622898; called by muse, mutect2, varscan2
- AOC1 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV62871262; called by muse, mutect2, varscan2
- ARHGAP39 | c.2166G>C p.W722C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52776361; called by muse, mutect2, varscan2
- ARID1A | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV61378702; called by muse, mutect2, varscan2
- ASB18 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs372467826; called by muse, mutect2, varscan2
- ASXL2 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55468976, COSV99078349; called by muse, mutect2, varscan2
- ASXL3 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52464733; called by muse, mutect2
- BCAS1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as COSV65083831; called by muse, varscan2
- BEST3 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58306388; called by muse, mutect2, varscan2
- BNIP5 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV71325889; called by muse, mutect2, varscan2
- C4orf19 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV52649057, COSV52650461; called by muse, mutect2, varscan2
- CAP2 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV57738083; called by muse, mutect2, varscan2
- CARD10 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.798); catalogued as rs1039088798, COSV52654755, COSV52657844; called by muse, mutect2, varscan2
- CCKBR | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs755245323, COSV58100685; called by muse, mutect2, varscan2
- CD1C | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63807848; called by muse, mutect2, varscan2
- CDCA7 | c.877C>T p.R293* (on ENST00000347703 / NM_145810.3; = p.R372* on NM_031942.5) | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV60720415; called by muse, mutect2, varscan2
- CDH11 | c.2195C>A p.P732H | Missense Mutation (SNP) | VAF 151/230 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51764385, COSV51779360; called by muse, mutect2, varscan2
- CELSR3 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as rs1274838828, COSV51168105; called by muse, mutect2, varscan2
- CEP85L | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as COSV63829199; called by muse, mutect2, varscan2
- CFAP221 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs570868554, COSV54661792; called by muse, mutect2, varscan2
- CFAP46 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1235887182, COSV63955389; called by muse, mutect2, varscan2
- CHD2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59122823; called by muse, varscan2
- CIAO2A | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV55539446; called by muse, varscan2
- CIAO2A | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV55539509; called by muse, varscan2
- CLK1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV58433794; called by muse, mutect2, varscan2
- CNOT10 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV59395806; called by muse, mutect2, varscan2
- CNTN1 | c.1462A>T p.N488Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61646392; called by muse, mutect2, varscan2
- CRYBG1 | c.3211C>G p.Q1071E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as rs757509100, COSV64814974; called by muse, mutect2, varscan2
- DDHD1 | c.878T>G p.I293R (on ENST00000323669; = p.I490R on NM_030637.3) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60363204; called by muse, mutect2, varscan2
- DHPS | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs765222214, COSV52953489; called by muse, mutect2, varscan2
- DIDO1 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1568861763, COSV56635247; called by muse, mutect2
- DISP2 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV51146420; called by muse, mutect2, varscan2
- DLL3 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52696010; called by muse, mutect2, varscan2
- DNAH17 | c.11767G>A p.D3923N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV67762046; called by muse, mutect2, varscan2
- DNAH8 | c.6800C>G p.S2267C | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59425324, COSV59484519; called by muse, mutect2, varscan2
- DNAH9 | c.8293G>A p.E2765K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV52379782; called by muse, mutect2, varscan2
- DNAJB12 | c.691G>A p.D231N (on ENST00000338820; = p.D197N on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147227290; called by muse, mutect2
- DPYS | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs368802826; called by mutect2, varscan2
- EHMT2 | c.3601G>C p.E1201Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV57667204, COSV57669409; called by muse, mutect2, varscan2
- ELF3 | c.398_408del p.S133* | Frame Shift Del (DEL) | VAF 59/133 reads (44%) | catalogued as COSV62840623; called by pindel, varscan2
- ELF3 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as COSV62840632; called by muse, mutect2, varscan2
- ELF3 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV62838350, COSV62839393; called by muse, mutect2, varscan2
- EPHA6 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs760704852, COSV67556568; called by muse, mutect2, varscan2
- EPN3 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52137474; called by muse, mutect2, varscan2
- EPS15L1 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV50176775; called by muse, mutect2, varscan2
- EXOC1 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV62122201; called by muse, mutect2, varscan2
- FABP9 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs750182639, COSV66911885; called by muse, mutect2, varscan2
- FAM234B | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754730917, COSV52198113; called by muse, mutect2, varscan2
- FKRP | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV59360339; called by muse, mutect2, varscan2
- FOXJ2 | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV50825749; called by muse, mutect2, varscan2
- GALC | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV54331142; called by muse, mutect2, varscan2
- GDF3 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.366); catalogued as COSV61713934; called by muse, mutect2
- GLDC | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58683338; called by muse, mutect2, varscan2
- GPR1 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67976846, COSV67977682; called by muse, mutect2, varscan2
- GPR17 | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55757429; called by muse, mutect2, varscan2
- GRM2 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56586875; called by muse, mutect2, varscan2
- GTPBP8 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV55607731; called by muse, mutect2, varscan2
- H3C2 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV52518592, COSV52519945, COSV99451484; called by muse, mutect2, varscan2
- HEATR3 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 12/181 reads (7%) | catalogued as COSV53528192; called by muse, mutect2
- HOXB4 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60179081; called by muse, mutect2, varscan2
- HOXB8 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV53311709; called by muse, mutect2, varscan2
- ICA1L | c.1311G>C p.Q437H | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV64175521; called by muse, mutect2, varscan2
- ICE1 | c.6625C>T p.P2209S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56833837; called by muse, mutect2, varscan2
- IFT81 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV54367020; called by muse, varscan2
- IGBP1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60557517; called by muse, mutect2, varscan2
- IGF2R | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63629316, COSV63633369; called by muse, mutect2, varscan2
- IQCB1 | c.1566G>C p.M522I | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60439804; called by muse, mutect2, varscan2
- ITGA4 | c.1351G>C p.G451R | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52004818, COSV52005211; called by muse, mutect2, varscan2
- ITGAD | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs746448725, COSV66760576; called by muse, mutect2, varscan2
- KAT5 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.296); catalogued as COSV100384019, COSV57729717; called by muse, mutect2, varscan2
- KCNA10 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as rs375380259; called by muse, mutect2, varscan2
- KDM1A | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773927280, COSV56505919; called by muse, mutect2, varscan2
- KIAA0753 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100810561, COSV63819110; called by muse, mutect2, varscan2
- KIAA1109 | c.14364G>C p.K4788N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52695796; called by muse, mutect2, varscan2
- KLHL12 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63042961; called by muse, varscan2
- KLHL12 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV63042966; called by muse, varscan2
- KRT39 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs769244028, COSV62917659; called by muse, mutect2, varscan2
- KRT6B | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as COSV52886947; called by muse, mutect2, varscan2
- KRT73 | c.1202G>A p.G401D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.108); catalogued as rs200649407, COSV59841917; called by muse, mutect2, varscan2
- KRTAP19-5 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs1189730720, COSV100478466, COSV61859758; called by muse, mutect2, varscan2
- LAMB4 | c.4738C>G p.Q1580E | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV52732642; called by muse, mutect2, varscan2
- LGR5 | c.1969C>G p.L657V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as rs552736723, COSV57010659; called by muse, mutect2, varscan2
- LMO7 | c.4747C>A p.Q1583K (on ENST00000357063; = p.Q1264K on NM_005358.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV58550761; called by muse, mutect2, varscan2
- LSM2 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1459543195, COSV65152126; called by muse, mutect2, varscan2
- MALSU1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV51694304; called by muse, mutect2, varscan2
- MAP4K4 | c.2917C>T p.L973F (on ENST00000347699 / NM_001242559.2; = p.L891F on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56341721; called by muse, mutect2, varscan2
- MCCC1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.868); catalogued as rs1054078378, COSV55612285; called by muse, mutect2, varscan2
- MCCC1 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55612297; called by muse, mutect2, varscan2
- MCCC1 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55612307; called by muse, mutect2, varscan2
- MCTP1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.115); catalogued as COSV56535603; called by muse, mutect2, varscan2
- MICAL2 | c.1949C>G p.S650C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56327310; called by muse, mutect2, varscan2
- MKI67 | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746950894, COSV64077454; called by muse, varscan2
- MKI67 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.626); catalogued as COSV64077456; called by muse, varscan2
- MLH1 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51625237; called by muse, mutect2, varscan2
- MOAP1 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52093976; called by muse, mutect2, varscan2
- MTMR2 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV60582350; called by muse, mutect2, varscan2
- MUC16 | c.8174C>G p.S2725C | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.187); catalogued as COSV67498694; called by muse, mutect2, varscan2
- MYCBP2 | c.2251G>A p.D751N (on ENST00000357337; = p.D789N on NM_015057.5) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV62041870; called by muse, mutect2, varscan2
- NEB | c.6832G>A p.E2278K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV51464984; called by muse, mutect2, varscan2
- NOL7 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs748208703, COSV50586626; called by muse, mutect2, varscan2
- NOS1 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760598926, COSV57615895; called by muse, mutect2, varscan2
- NOX5 | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV52997003; called by muse, mutect2, varscan2
- ONECUT1 | c.1012A>G p.S338G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs766909306, COSV59951203; called by muse, mutect2, varscan2
- OR11H12 | c.251T>C p.L84S | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs781191497, COSV73569370; called by muse, mutect2, varscan2
- OR4S1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs773257208, COSV60680378; called by muse, mutect2, varscan2
- OR4X2 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756487497, COSV56585408; called by muse, varscan2
- OR6B1 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as COSV68770176; called by muse, mutect2, varscan2
- PCDHGA1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); catalogued as COSV65295349; called by muse, mutect2, varscan2
- PCDHGA5 | c.1413C>G p.I471M | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV54046437; called by muse, mutect2, varscan2
- PCDHGA8 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs749009041, COSV53903990; called by muse, mutect2, varscan2
- PDCD4 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54525859; called by muse, mutect2, varscan2
- PDSS1 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV66060324; called by muse, mutect2, varscan2
- PGRMC1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54292650; called by muse, mutect2, varscan2
- PHB2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1565590009, COSV54644091; called by muse, mutect2, varscan2
- POLE | c.5878G>C p.D1960H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV57691894; called by muse, mutect2, varscan2
- POLR2B | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV58901884; called by muse, mutect2, varscan2
- POT1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV62927755, COSV62930107, COSV62930155; called by muse, mutect2, varscan2
- PPFIA1 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 68/241 reads (28%) | catalogued as COSV99558129; called by muse, mutect2, varscan2
- PPP1R9A | c.3096G>A p.M1032I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56913507; called by muse, mutect2, varscan2
- PPP4R4 | c.2314C>G p.R772G | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs147765941; called by muse, mutect2
- PRKD3 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV52219558; called by muse, varscan2
- PRPF40A | c.2700G>C p.E900D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs771850723, COSV68359666; called by muse, mutect2
- PSME4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV66368221; called by muse, mutect2, varscan2
- PTPRB | c.4822C>T p.P1608S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs750669874, COSV54255573; called by muse, mutect2, varscan2
- PTPRO | c.3121G>C p.E1041Q (on ENST00000281171 / NM_030667.3; = p.E1013Q on NM_002848.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55524434; called by muse, mutect2, varscan2
- RAD50 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as CD153893, COSV54758206; called by muse, varscan2
- RAD50 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs145031602; ClinVar: uncertain significance; called by muse, varscan2
- RADIL | c.300C>A p.Y100* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV68202501; called by muse, mutect2, varscan2
- RANBP2 | c.7821C>G p.I2607M | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV51699974; called by muse, mutect2, varscan2
- RBBP9 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61500419; called by muse, mutect2, varscan2
- RBP1 | c.52G>A p.E18K (on ENST00000619087 / NM_001365940.2; = p.E80K on NM_002899.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51678809; called by muse, mutect2, varscan2
- RFX6 | c.1270C>G p.Q424E | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1165017367, COSV60588597, COSV60589248; called by muse, mutect2, varscan2
- RNF6 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV60420740; called by muse, mutect2, varscan2
- RPGR | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV58840566; called by muse, mutect2, varscan2
- RXFP1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1439685174, COSV57054936, COSV57057597; called by muse, mutect2, varscan2
- SAMD4A | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV51888906; called by muse, mutect2, varscan2
- SCML2 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV52625502, COSV52625769; called by muse, mutect2, varscan2
- SEC16A | c.4322C>T p.S1441F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51542144; called by muse, mutect2, varscan2
- SEMA4B | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.662); catalogued as rs752137596, COSV60173104; called by muse, mutect2, varscan2
- SEMA4G | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52969480, COSV52972608; called by muse, mutect2, varscan2
- SETD5 | c.3903C>A p.S1301R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56717977; called by muse, mutect2, varscan2
- SH2D2A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1278367807, COSV63884278; called by muse, mutect2, varscan2
- SLC38A1 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV67065092; called by muse, mutect2, varscan2
- SLC46A3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs753121127, COSV57184981; called by muse, mutect2, varscan2
- SLC4A1AP | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV58138094; called by muse, mutect2, varscan2
- SLCO1B1 | c.1427A>G p.N476S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV57018239; called by muse, mutect2, varscan2
- SNRNP200 | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV60495117; called by muse, mutect2, varscan2
- SNTG2 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as rs1365306908, COSV58009173; called by muse, mutect2, varscan2
- SPAG4 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65331214; called by muse, mutect2, varscan2
- SPHKAP | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1056126785, COSV60868312, COSV60872962; called by muse, mutect2, varscan2
- SPRED1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54437401, COSV54439454; called by muse, mutect2, varscan2
- SPTBN2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs372241839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRCAP | c.8278G>A p.E2760K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs1300767984, COSV52682249; called by muse, mutect2
- STARD6 | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as rs754576270, COSV100323564; called by muse, mutect2, varscan2
- STX4 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV58269475; called by muse, mutect2, varscan2
- TBC1D22A | c.1401A>C p.E467D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1259323519, COSV61447493; called by muse, mutect2, varscan2
- TERF2 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54749340; called by muse, mutect2, varscan2
- TET2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); catalogued as COSV54423789, COSV54435489; called by muse, mutect2, varscan2
- TIMM44 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs200747180, COSV54495023; called by muse, mutect2, varscan2
- TMEM167B | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV57808700; called by muse, mutect2, varscan2
- TMEM67 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs146838062, COSV60045212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM35 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs777843116, COSV57767519; called by muse, mutect2, varscan2
- TRIM5 | c.786G>C p.L262F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59902483; called by muse, mutect2, varscan2
- TRPM3 | c.2458G>C p.E820Q (on ENST00000357533 / NM_001366142.2; = p.E663Q on NM_020952.6) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs764178764, COSV62596218; called by muse, mutect2, varscan2
- TSBP1 | c.1275G>C p.K425N (on ENST00000617061; = p.K430N on NM_006781.5) | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100898709, COSV66661070; called by muse, mutect2, varscan2
- TSC1 | c.2209-1G>C p.X737_splice | Splice Site (SNP) | VAF 46/72 reads (64%) | catalogued as COSV53774227, COSV53775497; called by muse, mutect2, varscan2
- TTN | c.47290A>G p.T15764A (on ENST00000591111; = p.T8340A on NM_003319.4) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | PolyPhen benign (0.079); catalogued as COSV60388022; called by muse, mutect2, varscan2
- USP54 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as rs1358315038, COSV60443599; called by muse, mutect2, varscan2
- VDR | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs190607107, COSV57470199; called by muse, mutect2, varscan2
- WDR12 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53689004; called by muse, mutect2, varscan2
- WDR33 | c.3807G>C p.Q1269H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV59256232; called by muse, mutect2, varscan2
- WLS | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV52047778; called by muse, mutect2, varscan2
- ZBTB11 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs957652882, COSV57247222; called by muse, mutect2, varscan2
- ZBTB12 | c.1343A>T p.E448V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV64994285; called by muse, mutect2, varscan2
- ZCCHC7 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV59721380; called by muse, mutect2, varscan2
- ZCCHC8 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV60320360; called by muse, mutect2, varscan2
- ZNF112 | c.1873C>G p.Q625E (on ENST00000337401 / NM_001083335.2; = p.Q619E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV61619387; called by muse, mutect2, varscan2
- ZNF229 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 25/179 reads (14%) | catalogued as COSV99351030; called by muse, mutect2, varscan2
- ZNF30 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.286); catalogued as COSV57853961, COSV57855535; called by muse, mutect2, varscan2
- ZNF671 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58054675; called by muse, mutect2, varscan2
- AJM1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.406); called by muse, mutect2
- CALHM2 | c.240del p.W80* | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- CARD14 | c.255del p.I86Sfs*7 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- COL6A6 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- DGKH | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ECM1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- GALNT3 | c.25A>T p.K9* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by mutect2, varscan2
- INTS4 | c.1790C>G p.S597* | Nonsense Mutation (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- KIAA0100 | c.1228dup p.R410Kfs*13 | Frame Shift Ins (INS) | VAF 96/200 reads (48%) | called by mutect2, varscan2
- KIAA1549L | c.4246G>T p.G1416* (on ENST00000321505; = p.G1713* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- MTRF1L | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.13976dup p.S4660Lfs*6 | Frame Shift Ins (INS) | VAF 46/166 reads (28%) | called by mutect2, pindel, varscan2
- NOXRED1 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- NUCB1 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 49/153 reads (32%) | called by muse, mutect2, varscan2
- NUDT19 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- PIK3C2B | c.4126G>T p.E1376* | Nonsense Mutation (SNP) | VAF 109/253 reads (43%) | called by muse, mutect2, varscan2
- PYCR1 | c.959G>C p.*320Sext*42 | Nonstop Mutation (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- SEZ6L | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 106/238 reads (45%) | called by muse, mutect2, varscan2
- SIL1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 54/141 reads (38%) | called by muse, mutect2, varscan2
- SRP9 | c.252_253delinsT p.E84Dfs*15 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by pindel, varscan2*
- TNK2 | c.2423C>G p.S808* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- WDR43 | c.172_174dup p.L58dup | In Frame Ins (INS) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- AC090517.4 | c.1998G>A p.K666= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV51001670; called by muse, mutect2
- ADAMTS12 | c.816C>T p.L272= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV61282388; called by muse, mutect2, varscan2
- AGAP1 | c.207C>T p.V69= | Silent (SNP) | VAF 50/221 reads (23%) | catalogued as rs774000052, COSV58340651; called by muse, mutect2, varscan2
- ANO7 | c.69G>A p.V23= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV51471555; called by muse, mutect2, varscan2
- APOB | c.12621A>G p.K4207= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV51955586; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2130A>T p.G710= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV57752699; called by muse, mutect2, varscan2
- BAZ2A | c.2703C>T p.V901= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV51644763; called by muse, mutect2, varscan2
- BCAS1 | c.591C>T p.F197= | Silent (SNP) | VAF 36/254 reads (14%) | catalogued as rs1257868712, COSV65086974; called by muse, varscan2
- CCDC39 | c.1908G>A p.E636= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as rs770356376, COSV56494858; called by muse, mutect2, varscan2
- CD248 | c.1404G>A p.V468= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as COSV60938058; called by muse, mutect2, varscan2
- CELF2 | c.138G>A p.Q46= (on ENST00000416382 / NM_001025077.3; = p.Q53= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV59983696; called by muse, mutect2, varscan2
- CHRNB2 | c.996G>A p.A332= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs762184252; called by mutect2, varscan2
- CHST1 | c.681C>G p.L227= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV57326075; called by muse, mutect2, varscan2
- COMT | c.570C>G p.L190= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV52891124; called by muse, mutect2, varscan2
- COQ8B | c.1056G>A p.T352= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs768934453, COSV54689429; called by muse, mutect2, varscan2
- CSNK1G2 | c.237C>T p.I79= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV55339226; called by muse, mutect2, varscan2
- DICER1 | c.5052C>T p.L1684= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV58629271; called by muse, mutect2, varscan2
- DISP1 | c.1065A>G p.G355= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV52665844; called by muse, mutect2
- DNAH11 | c.12285G>A p.L4095= | Silent (SNP) | VAF 43/167 reads (26%) | catalogued as rs746658722, COSV60985352; called by muse, mutect2, varscan2
- DNAH2 | c.5004G>A p.L1668= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV66728341; called by muse, mutect2
- DNTT | c.156C>T p.L52= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV64523784; called by muse, mutect2, varscan2
- DSP | c.5826C>A p.L1942= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV101131216, COSV65796560; called by muse, mutect2, varscan2
- ECI2 | c.267C>T p.N89= (on ENST00000380118 / NM_206836.3; = p.N59= on NM_006117.2) | Silent (SNP) | VAF 44/195 reads (23%) | catalogued as COSV60989655; called by muse, mutect2, varscan2
- EIF2B2 | c.93C>T p.S31= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV56721544; called by muse, mutect2, varscan2
- ERCC3 | c.2295G>A p.R765= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV53430422; called by muse, mutect2, varscan2
- FASLG | c.177G>A p.P59= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as rs559795993, COSV60679598; ClinVar: benign; called by muse, mutect2, varscan2
- FILIP1L | c.3321C>T p.V1107= (on ENST00000354552 / NM_182909.3; = p.V867= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/199 reads (20%) | catalogued as rs556347627, COSV58777006; called by muse, mutect2, varscan2
- GABBR1 | c.1983C>T p.F661= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs757538966, COSV63540632; called by muse, mutect2, varscan2
- GAREM1 | c.1038G>A p.V346= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV52516650; called by muse, mutect2, varscan2
- GMPPA | c.471G>A p.E157= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV58008801; called by muse, mutect2, varscan2
- GPR61 | c.642C>T p.V214= | Silent (SNP) | VAF 28/1097 reads (3%) | catalogued as COSV63984617; called by muse, mutect2
- H2BC4 | c.282G>A p.E94= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs747363195, COSV58415578, COSV58417740; called by muse, mutect2, varscan2
- IQCH | c.684G>C p.V228= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60060904; called by muse, mutect2, varscan2
- IRX5 | c.492C>T p.F164= | Silent (SNP) | VAF 31/264 reads (12%) | catalogued as COSV58058843; called by muse, mutect2, varscan2
- KCNB2 | c.1329C>T p.A443= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV73053268; called by muse, mutect2, varscan2
- KIAA0319L | c.1929G>A p.V643= | Silent (SNP) | VAF 72/187 reads (39%) | catalogued as rs1361753499, COSV57851456; called by muse, mutect2, varscan2
- KMT2D | c.6735C>G p.L2245= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV56492384; called by muse, mutect2, varscan2
- LIMS2 | c.540G>T p.L180= (on ENST00000355119 / NM_001161403.3; = p.L204= on NM_017980.4) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55757410; called by muse, mutect2, varscan2
- LRP1B | c.13695A>G p.L4565= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as rs1374232481, COSV67280578; called by muse, mutect2, varscan2
- MAD2L2 | c.87C>T p.L29= | Silent (SNP) | VAF 54/215 reads (25%) | catalogued as COSV52419380; called by muse, mutect2, varscan2
- MAP7 | c.2232G>A p.Q744= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV63423381; called by muse, mutect2, varscan2
- MAST1 | c.255C>T p.D85= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs201497430, COSV52256211; called by mutect2, varscan2
- MUC13 | c.102G>C p.A34= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV60700372, COSV60701553; called by muse, mutect2, varscan2
- NFASC | c.2586T>C p.Y862= (on ENST00000339876 / NM_001378329.1; = p.Y965= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV58382286; called by muse, mutect2, varscan2
- NRARP | c.344G>A p.*115= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs531591289; called by muse, mutect2
- NRIP1 | c.3342G>A p.T1114= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as rs201612350, COSV59655097; called by muse, mutect2, varscan2
- NUP205 | c.843C>T p.I281= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV53667081; called by muse, mutect2, varscan2
- OGDHL | c.2172C>A p.P724= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV65105037; called by muse, mutect2, varscan2
- OR6K6 | c.546C>T p.L182= (on ENST00000368144; = p.L158= on NM_001005184.1) | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV63745049; called by muse, mutect2, varscan2
- ORM2 | c.306G>A p.E102= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs1463015419, COSV52281368; called by muse, mutect2, varscan2
- PARD3B | c.3438G>A p.P1146= (on ENST00000406610 / NM_001302769.2; = p.P1077= on NM_057177.7) | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs780484580, COSV62533176; called by muse, mutect2, varscan2
- PHF12 | c.2424G>A p.V808= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV52022531; called by muse, mutect2, varscan2
- PIPOX | c.267G>A p.Q89= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV60142562, COSV60143973; called by muse, mutect2, varscan2
- PLCE1 | c.3762C>G p.L1254= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as COSV53374546; called by muse, varscan2
- POTEF | c.2202C>T p.I734= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as rs754228537, COSV100664899; called by muse, varscan2
- RBM41 | c.78G>A p.L26= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52565577; called by muse, mutect2, varscan2
- RGMB | c.174A>G p.K58= (on ENST00000513185 / NM_001366508.1; = p.K99= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 102/194 reads (53%) | catalogued as COSV57567226; called by muse, mutect2, varscan2
- SCN3A | c.1512G>A p.K504= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as COSV51826469; called by mutect2, varscan2
- SCN3A | c.774G>C p.L258= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV51817624; called by muse, mutect2, varscan2
- SERPING1 | c.1122C>T p.L374= | Silent (SNP) | VAF 82/209 reads (39%) | catalogued as COSV53543027; called by muse, mutect2, varscan2
- SLC39A6 | c.2184G>A p.Q728= | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as COSV52371726; called by muse, mutect2, varscan2
- SPSB3 | c.243C>T p.F81= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV51908855; called by muse, mutect2
- SPTBN1 | c.1920C>T p.L640= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV61695039; called by muse, mutect2, varscan2
- STIP1 | c.1536G>A p.Q512= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54184288; called by muse, mutect2, varscan2
- TCTE1 | c.294G>A p.K98= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV65256517; called by muse, mutect2, varscan2
- TRAM1 | c.480G>C p.L160= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV51600883; called by muse, mutect2, varscan2
- TRIM38 | c.636G>A p.L212= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV62643030; called by muse, mutect2, varscan2
- TTN | c.59214C>T p.T19738= (on ENST00000591111; = p.T12314= on NM_003319.4) | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as rs575396737, COSV60387985; called by muse, mutect2, varscan2
- USHBP1 | c.591G>A p.T197= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs767668171, COSV53106484; called by muse, mutect2, varscan2
- ZBTB22 | c.1125C>T p.V375= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as COSV56467959, COSV56473324; called by muse, mutect2, varscan2
- ZNF28 | c.1512C>T p.F504= | Silent (SNP) | VAF 34/211 reads (16%) | catalogued as COSV60425816; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849613 G>A | 5'Flank (SNP) | VAF 37/78 reads (47%) | catalogued as rs1331392533; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851498 T>C | 3'Flank (SNP) | VAF 51/325 reads (16%) | catalogued as rs1198872755; called by muse, mutect2, varscan2
- CCNP | c.514-82G>A | Intron (SNP) | VAF 58/155 reads (37%) | catalogued as COSV55688926; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 30/54 reads (56%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TP63 | c.1350-6261C>T | Intron (SNP) | VAF 28/142 reads (20%) | catalogued as COSV53222712; called by muse, mutect2, varscan2
